HCMI case HCM-CSHL-1270-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c95492e0-26ba-4a9c-a99b-f6aee9d33f20

Demographics
Sex at birth: male; Year of birth: 1957; Vital status: Dead; Days to death: 621 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,485 days); AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IVC; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 28 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 28 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 269 days; Days to treatment end: 311 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 332 days; Days to treatment end: 402 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 332 days; Days to treatment end: 402 days (1.1 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Encorafenib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 423 days (1.2 years); Days to treatment end: 534 days (1.5 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 548 days (1.5 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Radiation Therapy, NOS, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 63.2 years (23,077 days); Days to diagnosis: 592 days (1.6 years).
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 28 days; Days to treatment end: 170 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Irinotecan; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 28 days; Days to treatment end: 170 days; Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 621.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 173 cm; BMI: 24.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-1270-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1270-C18-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 2; Percent tumor nuclei: 2; Percent normal cells: 98; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-1270-C18-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-1270-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
